Surgical pathology report (de-identified scan), TCGA case TCGA-A6-A5ZU, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-A5ZU-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma NOS
8140/3
Site Transverse colon
018.4
Jed 4/12/13

Final Surgical Pathology Report

Procedure:

Diagnosis

Colon, ileocelectomy:

Moderately differentiated adenocarcinoma of the transverse colon
invasive through muscular wall into attached greater omentum (pT3)
Metastatic adenocarcinoma in 1 of 60 lymph nodes (pN1)
Extranodal tumor present
Serosal adhesions
Appendix with serosal adhesions
Resection margins negative

Microscopic Description:

Microscopic examination performed.

Histologic type: Adenocarcinoma, not otherwise specified

Histologic grade: Moderately differentiated

Primary tumor (pT): Invasive through muscularis propria of transverse
colon into attached greater omentum (pT3)

Proximal margin: Negative

Distal margins: Negative

Circumferential (radial) margin: Negative

Distance of tumor from closes margin: 8 cm from distal margin

Vascular invasion: Not identified

Regional lymph nodes (pN): One 60 lymph nodes is positive for
metastatic tumor (pN1)

Non-lymph node pericolic tumor: Present

Distant metastasis (pM): Not applicable (pMX)

Other findings: Serosal adhesions. Clinical obstruction. Appendix
with serosal adhesions. No specific additional pathologic
abnormalities identified the colon or the ileum.

MSI testing: Ordered on block A2

Pathologic stage T3N1 IIIB

Specimen

Right hemicolectomy

Clinical Information

Transverse colon cancer with clinical obstruction

[page 2 of 2]
Gross Description

Received fresh labeled "right hemicolectomy" is a previously unopened 40 cm segment of proximal right colon with attached 15 cm of distal ileum and an abundant amount of attached mesocolon, mesentery, and omentum. An unremarkable 9 cm appendix averaging 0.5 cm in diameter is present. The proximal and distal margins measure 5.2 and 7.8 cm in circumference respectively. On opening, there is a circumferential, 6.0 x 3.9 cm rubbery tan-white-red tumor mass which is 8 cm from the distal margin. On sectioning, the tumor has a maximal thickness of 2 cm, grossly extending through the muscularis and into the attached mesocolon. The tumor is present within 0.2 cm of the inked free radial serosal surface and visually appears to extend into the attached omentum. A 3 cm in greatest dimension area of tan red discoloration is noted within the distal ileum, 5 cm proximal to the ileocecal valve. The remaining ileal and colonic mucosa is unremarkable tan-pink with regular folds and the walls average 0.5 cm. A portion of tumor and a portion of normal colonic mucosa are submitted for tissue procurement as requested. Multiple soft to slightly rubbery tan-pink tissues in keeping with lymph nodes measuring up to 1.3 cm are recovered from the attached mesocolon and mesentery. RS 21

Summary: 1 - margins, 2 through 4 - tumor to inked free radial serosal surface (cassettes 3 and 4 including attached omentum), 5 and 6 - central tumor, 7 - discolored area of ileum, 8 - ICV, 9 and 10 the random from remainder of colon, 11 - appendix, 12 through 18 - 8 lymph nodes per cassette, 19 - 6 lymph nodes, 20 and 21 - 1 bisected lymph node per cassette

Source: NCI Genomic Data Commons file 2debd524-f9c0-4fd4-99d5-a7f40f502a15 (TCGA-A6-A5ZU.3E30630A-1BAB-480C-9C75-13E828907266.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).